Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A4BO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A4BO-01A (Primary Tumor).

[page 1 of 4]
Male

SURGICAL PATHOLOGY

Surgical Pathology

Surgical Pathology Report

[REDACTED]

M

CLINICAL INFORMATION:

Prostate cancer.

Specimen submitted: A. Right posterior apical margin (FS); B. Anterior apical margin (FS); C. Right base margin (FS); D. Prostate gland and seminal vesicles; E. Pelvic lymph nodes; F. Anterior prostatic fat

INTRAOPERATIVE DIAGNOSIS:

- A. Frozen section diagnosis: Fibromuscular tissue and adipose tissue and nerve. Reported to
- B. Frozen section diagnosis: Fibromuscular tissue and nerve. No prostatic gland or carcinoma seen. Reported to
- C. Frozen section diagnosis: Fibromuscular tissue with focal glandular epithelium, favor benign.. Reported to

GROSS DESCRIPTION:

- A. Received fresh, the specimen is labeled "right posterior apical margin (FS)," and consists of one piece of pink-tan soft tissue measuring 0.3 x 0.2 x 0.1 cm. 100% frozen. Summary of sections: AFSC.
- B. Received fresh, the specimen is labeled "anterior apical margin (FS)," and consists of one piece of pink-tan soft tissue measuring 0.2 x 0.1 x 0.1 cm. 100% frozen. Summary of sections: BFSC.

CCF: adenocarcinoma, section 855713
Path: adenocarcinoma, NOS 814613
Site: prostate, NOS C61.9
lu 9/30/12

ICB-0-3

[page 2 of 4]
C. Received fresh, the specimen is labeled "right base margin (FS)," and consists of one piece of pink-tan soft tissue measuring 0.3 x 0.2 x 0.1 cm. 100% frozen. Summary of sections: CFSC.

D. Received fresh, the specimen is labeled "prostate gland and seminal vesicles", and consists of a 60.2 gram radical prostatectomy specimen including a 6.0 x 5.5 x 5.3 cm prostate, a 3.5 x 1.5 x 0.7 cm left seminal vesicle, a 4.0 x 0.5 x 0.5 cm left vas deferens, a 4.0 x 2.0 x 0.6 cm right seminal vesicle and a 3.5 x 0.5 x 0.5 cm right vas deferens. The right side of the specimen is inked green, and the left side is inked black. The seminal vesicle base is amputated and submitted. The bladder neck and apical margins are amputated, perpendicularly sectioned, and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to C, respectively. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted in representative section. Summary of sections: D1-RSV; D2-LSV; D3-RA base; D4-RA base; D5-RP base; D6-RP base; D7-LA base; D8-LA base; D9-LP base; D10-LP base; D11-RA apex; D12-RP apex; D13-LA apex; D14-LP apex; D15-RAA1; D16-RPA1; D17-LAA1; D18-LPA1; D19-RAA2; D20-RPA2; D21-LAA2; D22-LPA2; D23-RAC; D24-RPC; D25-LAC and D26-LPC (Note: R=Right; L=Left; A=Anterior; P=posterior).

E. Received fresh, the specimen is labeled "pelvic lymph nodes," and consists of multiple, irregular pieces of fibroadipose tissue containing lymph nodes and measuring 7.0 x 3.0 x 2.0 cm in aggregate. Six lymph nodes are palpated and ranging in size from 1.4 cm to 2.5 cm in greatest dimension. The specimen is entirely submitted. Summary of sections: E1 through E2-one bisected lymph node (each cassette contains 1/2); E3 through E6-one bisected lymph node each; E7-one lymph node; E8-remaining tissue.

F. Received fresh, the specimen is labeled "anterior prostatic fat," and consists of an irregular piece of fibroadipose tissue measuring 2.0 x 1.5 x 0.2 cm. 100% submitted. Summary of sections: F1.

DIAGNOSIS:

- A. Prostate, right posterior apical margin (biopsy):
Benign fibromuscular tissue and nerve.
No prostatic glands or carcinoma seen.
- B. Prostate, anterior apical margin (biopsy):
Benign fibromuscular tissue and nerve.
No prostatic glands or carcinoma seen.
- C. Prostate, right base margin (biopsy):
Benign fibromuscular tissue.
Minute focus of benign crushed seminal vesicle
(original frozen only).
No prostatic glands or carcinoma seen.
- D. Prostate gland and seminal vesicles (radical prostatectomy):
Adenocarcinoma of the prostate, Gleason score 7
(3+4) with tertiary pattern 5, bilateral, organ confined.
Seminal vesicles and surgical margins are negative for

[page 3 of 4]
carcinoma.

Please see staging summary.

E. Lymph nodes, pelvic (excision):

Thirteen lymph nodes, negative for metastatic carcinoma
(0/13).

F. Anterior prostatic fat (excision):

Benign fibroadipose tissue.

No carcinoma identified.

SYNOPTIC DIAGNOSIS:

Histologic Type:
(conventional, not otherwise specified)

Adenocarcinoma

Primary Pattern: Grade 3
Secondary Pattern: Grade 4
Tertiary Pattern: Grade 5
Total Gleason Score: 7
Proportion (percent) of

Tumor Quantitation:

prostatic tissue involved by tumor: 8%

Pathologic Staging (pTNM):

pT2c: Bilateral disease
pN0: No regional lymph

node metastasis

Number of regional lymph

nodes examined: 13

Number of regional lymph

nodes involved: 0

pMX: Distant metastasis

cannot be assessed

Margins uninvolved by

Margins:

invasive carcinoma

Absent

Extraprostatic Extension:

Absent

Seminal Vesicle Invasion:

Present

Perineural Invasion:

Absent

Venous (Large Vessel) Invasion (V):

Absent

Lymphatic (Small Vessel) Invasion (L):

High-grade prostatic

Additional Pathologic Findings:

intraepithelial neoplasia (PIN)

/ ** Electronically Signed Out **

Attending Pathologist

The attending pathologist whose signature appears on this
report has reviewed the diagnostic slides, and has edited
the gross and microscopic portions of the report in rendering the
final diagnosis.

ICD9 Codes: A-F: 185

SNOMED:

Slides: A-3; B-2; C-2; D-26; E-8; F-1

[page 4 of 4]
Resulting Agency

IP-3A Discrepancy		
Ascites (circle)		

Source: NCI Genomic Data Commons file 1fdc9be6-fd92-4547-a718-807996c36435 (TCGA-KC-A4BO.C601C012-0EC4-4386-9A9A-3485FD4968E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).